Gene-level copy-number profile of tumor specimen TCGA-D7-A6F2-01A from TCGA case TCGA-D7-A6F2, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.4 years (22,801 days).
Specimen TCGA-D7-A6F2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.8dea2381-5522-4d1d-ac2e-3d6ab173e444.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D7-A6F2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cca0db18-ebb7-41c1-aa33-45b0e11088bb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,006; copy number 2: 15,946; copy number 3: 22,892; copy number 4: 11,459; copy number 5: 4,640; copy number 6: 1,297; copy number 7: 1,176; copy number 8: 1,065; copy number 11: 131; copy number 14: 3; copy number 15: 76; copy number 16: 7; copy number 18: 55; copy number 24: 20; copy number 27: 20; copy number 35: 3; copy number 39: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D7-A6F2-01A-12D-A31K-01): tumor purity 0.63, ploidy 3.44, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:108,551,018–108,551,207, 1 gene: AL391646.1.
- chr13:44,094,822–44,256,596, 7 genes: LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1.
- chr19:16,197,854–16,328,685, 3 genes (within-gene range 0–2): AP1M1, AC020911.2, KLF2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,562 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:3,595,832–4,440,259, 6 genes, copy number 16: IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063, AC106799.3.
- chr5:4,512,262–4,516,776, 1 gene, copy number 16: AC106799.1.
- chr8:73,670,441–75,566,834, 39 genes, copy number 8: AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:78,148,101–80,231,232, 29 genes, copy number 8 (within-gene range 6–8): AC084706.1, PKIA-AS1, RNU6-1220P, PKIA, AC068700.1, AC068700.2, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605, AC138646.1, AC100870.1, RPL3P9, STMN2, AC016240.1, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P.
- chr8:83,200,952–145,066,685, 973 genes, copy number 7 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 8 (broad region; genes not listed).
- chr12:61,600,067–62,279,150, 6 genes, copy number 39 (within-gene range 2–39): DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:69,212,108–73,208,317, 65 genes, copy number 14–35 (broad region; genes not listed).
- chr13:23,730,189–33,676,796, 203 genes, copy number 7 (broad region; genes not listed).
- chr16:11,555–1,702,280, 145 genes, copy number 8 (broad region; genes not listed).
- chr16:1,707,252–1,714,208, 2 genes, copy number 8: AL031710.2, AL031710.1.
- chr17:37,084,992–37,406,836, 1 gene, copy number 11 (within-gene range 6–11): ACACA.
- chr17:37,375,985–41,966,503, 242 genes, copy number 11–24 (within-gene range 5–24) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,001. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
